Somatic mutation profile of tumor specimen 0D9CML from CCDI case PBBIJB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 17.1 years (6,257 days).
Specimen 0D9CML: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c846efb7-7874-493f-aeb5-d28f0c2593f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9CMM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5b79ede-70f8-4237-9383-c74c439a3d76

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DGKB | c.2094A>T p.T698= | Silent (SNP) | VAF 78/518 reads (15%) | called by muse, mutect2, varscan2
- TMEM104 | c.933C>T p.Y311= | Silent (SNP) | VAF 27/627 reads (4%) | catalogued as rs772099060, COSV59109803; called by muse, mutect2
